Somatic mutation profile of tumor specimen C3N-02281-02 (aliquot CPT0125410007) from CPTAC case C3N-02281, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 63.5 years (23,197 days).
Specimen C3N-02281-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d23a8a5f-3bc6-4d18-ab6a-ce932c66a9d7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02281-31 (Blood Derived Normal), aliquot CPT0126370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3e877e0-19d6-433c-8161-ef52212b2401

The open-access MAF lists 707 somatic variants for this specimen: 478 protein-altering or splice-affecting, 136 silent, 93 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 418, Silent 136, Intron 43, Nonsense Mutation 31, RNA 20, 3'UTR 16, Splice Site 11, Frame Shift Del 10, 5'Flank 6, 3'Flank 4, 5'UTR 4, Splice Region 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 85/246 reads (35%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC3A1 | c.1414C>T p.L472F | Missense Mutation (SNP) | VAF 45/307 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373176089, HM070022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AADACL4 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.735); catalogued as rs967595253; called by muse, mutect2, varscan2
- ABCC11 | c.2688C>A p.H896Q | Missense Mutation (SNP) | VAF 31/179 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs779122178; called by muse, mutect2, varscan2
- AC011005.1 | c.905G>T p.R302L | Missense Mutation (SNP) | VAF 95/279 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.076); catalogued as rs763418952; called by muse, mutect2, varscan2
- ACSM2B | c.124G>T p.A42S | Missense Mutation (SNP) | VAF 34/226 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.042); catalogued as COSV100312292; called by muse, mutect2, varscan2
- ACTA1 | c.1043T>A p.L348Q | Missense Mutation (SNP) | VAF 28/384 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as CM153370; called by muse, mutect2
- ADAP2 | c.301C>T p.Q101* | Nonsense Mutation (SNP) | VAF 40/222 reads (18%) | catalogued as COSV100437101; called by muse, mutect2, varscan2
- ADCY8 | c.498G>T p.L166F | Missense Mutation (SNP) | VAF 53/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755362129, COSV99652501; called by muse, mutect2, varscan2
- ADGRB3 | c.615G>T p.W205C | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.431); catalogued as COSV65411288; called by muse, mutect2
- AFDN | c.2458C>T p.R820C | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780592632, COSV100653602; called by muse, mutect2, varscan2
- AGO1 | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 102/268 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64596301; called by muse, mutect2, varscan2
- AGPAT4 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 60/556 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.78); catalogued as rs781252538, COSV57248906; called by muse, mutect2, varscan2
- AHNAK | c.4232_4234del p.V1411del | In Frame Del (DEL) | VAF 30/338 reads (9%) | catalogued as rs1381578078; called by mutect2, pindel
- AICDA | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 35/437 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV57563480; called by muse, mutect2
- ALPK3 | c.1123G>T p.A375S | Missense Mutation (SNP) | VAF 65/244 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV51931558; called by muse, mutect2, varscan2
- ANK2 | c.8606C>A p.S2869Y | Missense Mutation (SNP) | VAF 28/356 reads (8%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.165); catalogued as rs776692426; called by muse, mutect2
- ARAF | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.083); catalogued as rs749564014, COSV99283529; called by muse, mutect2
- ARHGAP28 | c.195C>G p.S65R | Missense Mutation (SNP) | VAF 23/214 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.296); catalogued as COSV99151208; called by muse, mutect2, varscan2
- ASH1L | c.4522C>T p.R1508* | Nonsense Mutation (SNP) | VAF 20/256 reads (8%) | catalogued as COSV99054597; called by muse, mutect2
- ASTN2 | c.1876C>G p.P626A (on ENST00000313400 / NM_001365069.1; = p.P575A on NM_014010.5) | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs202209251; called by muse, mutect2, varscan2
- ASTN2 | c.1101C>G p.I367M | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.957); catalogued as rs140458736; called by muse, mutect2
- ATP4A | c.1747G>A p.D583N | Missense Mutation (SNP) | VAF 36/353 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as rs200791532, COSV52866645; called by muse, mutect2
- ATRX | c.4039G>T p.V1347L | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV100971137; called by muse, mutect2
- BARD1 | c.994A>G p.I332V | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs543606863; called by muse, mutect2, varscan2
- BPIFB2 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 58/312 reads (19%) | catalogued as rs1484088885; called by muse, mutect2, varscan2
- BRSK1 | c.512G>T p.R171L | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100510223; called by muse, mutect2, varscan2
- BRWD3 | c.1592C>G p.T531R | Missense Mutation (SNP) | VAF 12/243 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV64744539; called by muse, mutect2
- CCDC15 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 15/155 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.082); catalogued as rs1166271506; called by muse, mutect2
- CCDC81 | c.1180G>T p.A394S (on ENST00000445632 / NM_001156474.2; = p.A304S on NM_021827.4) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as COSV99564990; called by muse, mutect2, varscan2
- CCNB3 | c.1214A>T p.E405V | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV52071489; called by muse, mutect2, varscan2
- CD276 | c.1295C>T p.A432V (on ENST00000318443 / NM_001024736.2; = p.A214V on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/497 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs775977755, COSV59204592; called by muse, mutect2, varscan2
- CDHR2 | c.913C>A p.R305S | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56136138; called by muse, mutect2, varscan2
- CEACAM8 | c.577C>A p.L193M | Missense Mutation (SNP) | VAF 88/628 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99747840; called by muse, mutect2, varscan2
- CEP250 | c.5164G>A p.G1722R | Missense Mutation (SNP) | VAF 36/440 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.943); catalogued as rs1453778388; called by muse, mutect2
- CHST8 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 25/123 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52861666; called by muse, mutect2, varscan2
- CNGA4 | c.848A>G p.H283R | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1213177677; called by muse, mutect2
- CNGB1 | c.2255A>G p.Y752C | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.442); catalogued as rs758957796; called by muse, mutect2
- CNTNAP5 | c.2377G>T p.V793F | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV70476456; called by muse, mutect2
- COL4A6 | c.1562G>C p.G521A | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT tolerated (0.79); PolyPhen benign (0.098); catalogued as COSV57875512; called by muse, mutect2, varscan2
- CRACD | c.1618C>T p.Q540* | Nonsense Mutation (SNP) | VAF 8/120 reads (7%) | catalogued as COSV99949038; called by muse, mutect2
- CSF2RB | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 20/238 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs202215481, COSV53255896; called by muse, mutect2
- CSMD1 | c.718G>T p.A240S | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as rs976805037; called by muse, mutect2
- CYP2A13 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs549735222, COSV57838110, COSV57839438; called by muse, mutect2, varscan2
- DCST2 | c.1053G>T p.W351C | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.339); catalogued as COSV55055580; called by muse, mutect2, varscan2
- DNAH5 | c.4664G>T p.W1555L | Missense Mutation (SNP) | VAF 53/183 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54202899; called by muse, mutect2, varscan2
- DOCK10 | c.1937C>A p.A646D | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.05); catalogued as COSV51405216; called by muse, mutect2, varscan2
- DROSHA | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as rs760926045; called by muse, mutect2, varscan2
- DYSF | c.3290G>T p.R1097L | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV50296611, COSV50456471; called by muse, mutect2, varscan2
- ECSIT | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs746082835, COSV52939260; called by muse, mutect2
- ERICH3 | c.3356C>T p.P1119L | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV100444288, COSV58620064; called by muse, mutect2, varscan2
- F9 | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as CD125311, CM045748; called by muse, mutect2, varscan2
- FAM155A | c.1374G>C p.E458D | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV65576080; called by muse, varscan2
- FCRL1 | c.156C>A p.F52L | Missense Mutation (SNP) | VAF 89/354 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100839835; called by muse, mutect2, varscan2
- FRMPD3 | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV52189801; called by muse, mutect2, varscan2
- GAGE10 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 65/471 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs376577624, COSV68164020, COSV68164057; called by muse, mutect2, varscan2
- GANAB | c.2719A>G p.T907A | Missense Mutation (SNP) | VAF 23/213 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1313521554; called by muse, mutect2, varscan2
- GK2 | c.958G>T p.G320C | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62626446; called by muse, mutect2
- GP2 | c.1102G>A p.E368K (on ENST00000381362 / NM_001007240.3; = p.E365K on NM_001502.4) | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV56892940; called by muse, mutect2
- GPC5 | c.239C>T p.A80V | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.053); catalogued as rs559277707, COSV65579895; called by muse, mutect2
- GRAP2 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 16/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV59994224; called by muse, mutect2, varscan2
- GTF3C1 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 51/336 reads (15%) | catalogued as COSV62240855; called by muse, mutect2, varscan2
- GTPBP4 | c.1606G>T p.D536Y | Missense Mutation (SNP) | VAF 9/271 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV52989416; called by muse, mutect2
- H2AC17 | c.205A>G p.N69D | Missense Mutation (SNP) | VAF 83/414 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV58153452; called by muse, mutect2, varscan2
- H3C4 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 38/575 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61912085; called by muse, mutect2
- H4C13 | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 20/178 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.667); catalogued as COSV60693450; called by muse, mutect2
- HAPLN4 | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 68/314 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.319); catalogued as COSV52269702; called by muse, mutect2, varscan2
- HAS3 | c.118A>C p.K40Q | Missense Mutation (SNP) | VAF 55/302 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs966724943; called by muse, mutect2, varscan2
- HOOK3 | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1324003599; called by muse, mutect2, varscan2
- IDI2 | c.146T>G p.L49R | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs550879358; called by muse, mutect2, varscan2
- IQCA1 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760111545, COSV54513151; called by muse, mutect2, varscan2
- ITGAL | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 21/267 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV63323757; called by muse, mutect2
- KCNK3 | c.416T>A p.L139Q | Missense Mutation (SNP) | VAF 35/97 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100257045; called by muse, mutect2, varscan2
- KCNV2 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 26/384 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.255); catalogued as rs776522169; called by muse, mutect2
- KCTD3 | c.301G>T p.G101W | Missense Mutation (SNP) | VAF 20/121 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52064562; called by muse, mutect2, varscan2
- KCTD3 | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 20/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52065643; called by muse, mutect2, varscan2
- KIAA1841 | c.608G>T p.W203L | Missense Mutation (SNP) | VAF 27/293 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54375250; called by muse, mutect2
- KIF2B | c.1774C>A p.Q592K | Missense Mutation (SNP) | VAF 9/136 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV52128578, COSV52129153; called by muse, mutect2
- LAMA4 | c.4689C>A p.S1563R (on ENST00000230538 / NM_001105206.3; = p.S1556R on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.667); catalogued as rs1554325276; called by muse, mutect2, varscan2
- LINGO2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.803); catalogued as rs1329891686, COSV58061180; called by muse, mutect2
- LMO2 | c.439G>T p.D147Y (on ENST00000395833 / NM_001142315.2; = p.D216Y on NM_005574.4) | Missense Mutation (SNP) | VAF 37/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57645578; called by muse, mutect2, varscan2
- LPO | c.1918C>A p.R640S | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51859826; called by muse, varscan2
- LRP1B | c.7993T>A p.C2665S | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67257911; called by muse, mutect2, varscan2
- LRP2 | c.12421G>C p.V4141L | Missense Mutation (SNP) | VAF 20/224 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as rs150382715, COSV99789745; called by muse, mutect2
- MAGEL2 | c.2952C>G p.S984R | Missense Mutation (SNP) | VAF 60/180 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs573975752, COSV100046329; called by muse, mutect2, varscan2
- MAP3K20 | c.208G>C p.G70R | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59105405; called by muse, mutect2, varscan2
- MKRN3 | c.1237G>T p.G413* | Nonsense Mutation (SNP) | VAF 74/357 reads (21%) | catalogued as COSV58812197; called by muse, mutect2, varscan2
- MRC1 | c.2389C>A p.P797T | Missense Mutation (SNP) | VAF 25/435 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.11); catalogued as rs1211328348; called by muse, mutect2
- MRC2 | c.2350G>T p.G784C | Missense Mutation (SNP) | VAF 44/561 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.606); catalogued as rs1215926939; called by muse, mutect2
- MSH4 | c.520G>T p.A174S | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54202472; called by muse, mutect2, varscan2
- NBEA | c.3235G>T p.E1079* | Nonsense Mutation (SNP) | VAF 7/131 reads (5%) | catalogued as COSV100082458; called by muse, mutect2
- NCOR1 | c.4366C>T p.P1456S | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.9); PolyPhen benign (0.024); catalogued as rs1326612685; called by muse, mutect2, varscan2
- NEBL | c.369+1G>T p.X123_splice | Splice Site (SNP) | VAF 94/272 reads (35%) | catalogued as COSV65800303; called by muse, mutect2, varscan2
- NEK8 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 31/208 reads (15%) | catalogued as COSV99261739; called by muse, mutect2, varscan2
- NLRP3 | c.2359G>T p.D787Y | Missense Mutation (SNP) | VAF 315/769 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as COSV100275005; called by muse, mutect2, varscan2
- NPAP1 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61505168, COSV61507605; called by muse, mutect2, varscan2
- OBSCN | c.13930G>T p.E4644* | Nonsense Mutation (SNP) | VAF 193/515 reads (37%) | catalogued as COSV52826878; called by muse, mutect2, varscan2
- OR5B2 | c.768C>G p.I256M | Missense Mutation (SNP) | VAF 100/372 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs754228444, COSV100222761; called by muse, mutect2, varscan2
- OR5T3 | c.166G>T p.G56W | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57379584, COSV57382537; called by muse, mutect2, varscan2
- OR7C1 | c.349G>A p.V117M | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.304); catalogued as COSV50183117; called by muse, mutect2, varscan2
- OSBPL6 | c.1028C>A p.S343Y | Missense Mutation (SNP) | VAF 30/312 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV99508389; called by muse, mutect2
- OTC | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 58/345 reads (17%) | catalogued as CD962115; called by muse, mutect2, varscan2
- OTOA | c.3404C>A p.S1135* (on ENST00000286149; = p.S1121* on NM_144672.4) | Nonsense Mutation (SNP) | VAF 65/463 reads (14%) | catalogued as COSV99625592; called by muse, mutect2, varscan2
- OXCT1 | c.1435del p.D479Tfs*6 | Frame Shift Del (DEL) | VAF 92/298 reads (31%) | catalogued as COSV52169247; called by mutect2, pindel, varscan2
- PAPPA2 | c.957A>T p.K319N | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62782341; called by muse, mutect2, varscan2
- PASD1 | c.2008C>A p.P670T | Missense Mutation (SNP) | VAF 13/354 reads (4%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.556); catalogued as COSV64853891, COSV64854644; called by muse, mutect2
- PCDH9 | c.3148C>A p.R1050S (on ENST00000377865 / NM_203487.3; = p.R1016S on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100117873; called by muse, mutect2
- PCDHA12 | c.1705C>T p.P569S | Missense Mutation (SNP) | VAF 205/746 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.007); catalogued as COSV56552394; called by muse, mutect2, varscan2
- PCDHGA11 | c.2194G>T p.G732W | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as COSV53912125, COSV54010412; called by muse, mutect2, varscan2
- PCDHGA5 | c.2200G>T p.G734C | Missense Mutation (SNP) | VAF 109/442 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); catalogued as COSV99038453; called by muse, mutect2, varscan2
- PCLO | c.4063A>G p.K1355E | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV61630193; called by muse, mutect2
- PCSK2 | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV99359504; called by muse, mutect2, varscan2
- PEX5L | c.149C>A p.P50Q | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55841879, COSV99828249, COSV99828975; called by muse, mutect2, varscan2
- PLXNA3 | c.3658G>T p.A1220S | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100860029; called by muse, mutect2
- PLXNB3 | c.1433C>T p.P478L | Missense Mutation (SNP) | VAF 45/379 reads (12%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as rs782809682; called by muse, mutect2, varscan2
- PPFIA2 | c.2333C>A p.T778N | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1323642748, COSV61054317; called by muse, mutect2, varscan2
- PPP1R16B | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 20/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777435988, COSV55377423; called by muse, mutect2
- PRPF38B | c.229T>C p.Y77H | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); catalogued as COSV64223641; called by muse, mutect2
- PRRT4 | c.560G>A p.G187D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs757097456; called by muse, mutect2, varscan2
- PTCHD4 | c.1579C>G p.L527V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.1); catalogued as COSV59777617, COSV59798042; called by muse, mutect2, varscan2
- PTPRD | c.4775G>T p.R1592M | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61943529; called by muse, mutect2, varscan2
- RIMS2 | c.2497G>A p.E833K (on ENST00000666250 / NM_001348490.2; = p.E641K on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1287731139; called by muse, mutect2
- RIMS2 | c.2882G>A p.R961Q (on ENST00000666250 / NM_001348490.2; = p.R769Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.755); catalogued as rs368813886; called by muse, mutect2, varscan2
- RNF17 | c.2581G>T p.G861C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55050220; called by muse, mutect2, varscan2
- RPN1 | c.24G>C p.L8F | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.089); catalogued as rs1361136875; called by muse, varscan2
- RRAGB | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs745423992, COSV99469539; called by muse, mutect2, varscan2
- SCN11A | c.712+1G>T p.X238_splice | Splice Site (SNP) | VAF 32/97 reads (33%) | catalogued as rs768647693, COSV56566760; called by muse, mutect2, varscan2
- SEL1L2 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 45/226 reads (20%) | catalogued as COSV53150530; called by muse, mutect2, varscan2
- SERPINA12 | c.1198C>A p.P400T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as rs1356786486; called by muse, mutect2
- SGSM2 | c.1436C>T p.P479L (on ENST00000426855 / NM_001098509.2; = p.P524L on NM_014853.3) | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99280625; called by muse, mutect2, varscan2
- SI | c.3136G>T p.V1046L | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs777140192, COSV52274373; called by muse, mutect2, varscan2
- SLC35F1 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100838197; called by muse, mutect2
- SLC38A5 | c.319+1G>T p.X107_splice | Splice Site (SNP) | VAF 51/308 reads (17%) | catalogued as rs868973340; called by muse, mutect2, varscan2
- SLC39A12 | c.1154C>A p.T385K | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.259); catalogued as COSV66196576; called by muse, mutect2
- SLC7A3 | c.586G>C p.V196L | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.034); catalogued as COSV53227379; called by muse, mutect2
- SPAG17 | c.3128G>T p.G1043V | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60456653; called by muse, mutect2, varscan2
- SPATC1 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 55/187 reads (29%) | catalogued as COSV66298463; called by muse, mutect2, varscan2
- SRPX | c.50T>C p.L17P | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs201383079; called by muse, varscan2
- SRRM2 | c.5734C>T p.R1912W | Missense Mutation (SNP) | VAF 17/181 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as rs748024471; called by muse, mutect2
- SSTR1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.663); catalogued as COSV57456694, COSV99942871; called by muse, mutect2
- ST8SIA3 | c.635C>A p.P212H | Missense Mutation (SNP) | VAF 34/223 reads (15%) | PolyPhen probably damaging (0.995); catalogued as COSV100129727; called by muse, mutect2, varscan2
- STAP1 | c.29C>A p.A10D | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99609315; called by muse, mutect2
- STK11IP | c.1390G>A p.D464N | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.039); catalogued as rs752821805, COSV99822465; called by muse, mutect2, varscan2
- SYNE1 | c.9355C>T p.H3119Y (on ENST00000367255 / NM_182961.4; = p.H3126Y on NM_033071.3) | Missense Mutation (SNP) | VAF 11/137 reads (8%) | SIFT tolerated (0.89); PolyPhen benign (0.358); catalogued as rs373615823; called by muse, mutect2
- TBXAS1 | c.689-8C>A | Splice Region (SNP) | VAF 120/389 reads (31%) | catalogued as rs764602706; called by muse, mutect2, varscan2
- TCF21 | c.297C>G p.F99L | Missense Mutation (SNP) | VAF 57/342 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV99399516; called by muse, mutect2, varscan2
- TET1 | c.3334G>A p.V1112I | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs1489796126; called by muse, mutect2
- TGFBR2 | c.1197del p.L400Ffs*31 | Frame Shift Del (DEL) | VAF 7/84 reads (8%) | catalogued as COSV55446124; called by mutect2, pindel
- THSD7B | c.1577G>T p.G526V | Missense Mutation (SNP) | VAF 22/203 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55698993, COSV55736125; called by muse, mutect2, varscan2
- TMEM196 | c.377G>C p.C126S | Missense Mutation (SNP) | VAF 89/194 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV101337431; called by muse, mutect2, varscan2
- TMEM200A | c.749G>T p.S250I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.276); catalogued as rs748777286, COSV99758817; called by muse, mutect2, varscan2
- TOMM70 | c.1480A>G p.K494E | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.306); catalogued as rs769810811; called by muse, mutect2, varscan2
- TP53 | c.504C>G p.H168Q | Missense Mutation (SNP) | VAF 90/321 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52761294, COSV52774171, COSV53097694; called by muse, mutect2, varscan2
- TRAK2 | c.2075G>T p.G692V | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as rs1242636571; called by muse, varscan2
- TRDN | c.1321G>T p.A441S | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.321); catalogued as rs930768075; called by muse, mutect2, varscan2
- TRO | c.416C>A p.A139D | Missense Mutation (SNP) | VAF 16/195 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); catalogued as COSV51498209; called by muse, mutect2
- TUT7 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 8/43 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as rs779155171; called by muse, mutect2, varscan2
- VWA3B | c.2635G>T p.V879F | Missense Mutation (SNP) | VAF 69/205 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs370362777, COSV68241082; called by muse, mutect2, varscan2
- VWF | c.203G>C p.R68P | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV54610986; called by muse, mutect2
- WDFY4 | c.8269G>C p.D2757H | Missense Mutation (SNP) | VAF 81/354 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99629666; called by muse, mutect2, varscan2
- WDR44 | c.1480C>A p.P494T | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99561139; called by muse, mutect2, varscan2
- WDR87 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.03); catalogued as rs931240129; called by muse, mutect2, varscan2
- XIRP2 | c.8497G>T p.V2833L (on ENST00000628543; = p.V3008L on NM_152381.6) | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as rs768815973; called by muse, mutect2, varscan2
- ZFHX4 | c.5159C>T p.P1720L | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755498809; called by muse, mutect2, varscan2
- ZIC3 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 44/299 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as COSV99799656; called by muse, varscan2
- ZNF141 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 15/169 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1274759326; called by muse, mutect2
- ZNF208 | c.809C>G p.A270G | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.167); catalogued as COSV101236631; called by muse, varscan2
- ZNF292 | c.1694A>G p.K565R | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs1277211789; called by muse, mutect2, varscan2
- ZNF534 | c.496T>G p.F166V (on ENST00000332323 / NM_001143939.3; = p.F153V on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56519584; called by muse, mutect2, varscan2
- ABCA2 | c.4093G>C p.D1365H (on ENST00000614293; = p.D1335H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCA7 | c.5192G>T p.G1731V | Missense Mutation (SNP) | VAF 61/242 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB7 | c.985G>T p.A329S (on ENST00000373394 / NM_001271696.3; = p.A330S on NM_004299.6) | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.627); called by muse, mutect2
- ACTN3 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 18/274 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.632); called by muse, mutect2
- ADAMTS1 | c.2479A>G p.T827A | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS12 | c.4721C>T p.T1574I | Missense Mutation (SNP) | VAF 36/462 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.055); called by muse, mutect2
- ADGRB2 | c.4667C>A p.P1556H (on ENST00000373658 / NM_001364857.2; = p.P1555H on NM_001294335.2) | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- ADGRG4 | c.110del p.G37Efs*7 | Frame Shift Del (DEL) | VAF 8/63 reads (13%) | called by mutect2, pindel, varscan2
- ADNP2 | c.3284G>T p.R1095M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AIPL1 | c.710G>T p.C237F | Missense Mutation (SNP) | VAF 73/265 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- AJM1 | c.2230T>A p.F744I | Missense Mutation (SNP) | VAF 33/309 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- AL031777.2 | c.409G>T p.V137L | Missense Mutation (SNP) | VAF 14/235 reads (6%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2
- AL121899.2 | c.847G>T p.G283C | Missense Mutation (SNP) | VAF 38/262 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- ANKRD35 | c.1501G>T p.A501S | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ANKRD42 | c.613C>A p.L205M | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.031); called by muse, varscan2
- APOB | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- ARHGAP36 | c.839T>A p.V280E | Missense Mutation (SNP) | VAF 15/180 reads (8%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.824); called by muse, mutect2
- ARHGEF26 | c.994A>T p.S332C | Missense Mutation (SNP) | VAF 94/461 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ASB6 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 12/224 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.889); called by muse, mutect2
- ASH1L | c.1933A>T p.R645* | Nonsense Mutation (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- ATP6AP1 | c.772G>C p.V258L | Missense Mutation (SNP) | VAF 62/562 reads (11%) | SIFT tolerated (0.34); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ATP6AP1 | c.1348C>G p.L450V | Missense Mutation (SNP) | VAF 32/444 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- AURKAIP1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 23/470 reads (5%) | called by muse, mutect2
- AXDND1 | c.1592C>A p.T531N | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- B4GALT4 | c.533A>T p.Y178F | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- BCORL1 | c.1373G>T p.G458V | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- BGN | c.397G>T p.A133S | Missense Mutation (SNP) | VAF 55/392 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- BRWD3 | c.1102G>T p.V368F | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- C1orf87 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- CA2 | c.35-1G>T p.X12_splice | Splice Site (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- CABP1 | c.850G>T p.D284Y (on ENST00000316803 / NM_001033677.1; = p.D81Y on NM_004276.5) | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- CALB2 | c.786G>T p.E262D | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- CAMKK2 | c.701A>C p.Y234S | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CAPN6 | c.1078T>C p.W360R | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CAPS2 | c.670A>G p.K224E | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.26); called by muse, mutect2
- CARS1 | c.1819+1G>T p.X607_splice | Splice Site (SNP) | VAF 15/104 reads (14%) | called by muse, mutect2, varscan2
- CATIP | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 28/145 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CATIP | c.1066C>T p.P356S | Missense Mutation (SNP) | VAF 114/661 reads (17%) | SIFT tolerated (0.94); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CCDC106 | c.597G>T p.M199I | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- CCDC168 | c.9908A>G p.K3303R | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.373); called by muse, mutect2
- CCDC168 | c.153G>T p.E51D | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCNB3 | c.743C>A p.S248* | Nonsense Mutation (SNP) | VAF 16/154 reads (10%) | called by muse, mutect2
- CD70 | c.473T>A p.L158Q | Missense Mutation (SNP) | VAF 53/315 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CDH10 | c.551C>A p.A184D | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH20 | c.2050T>A p.W684R | Missense Mutation (SNP) | VAF 69/383 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CDH9 | c.1535T>C p.M512T | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDHR1 | c.1513G>T p.G505C | Missense Mutation (SNP) | VAF 40/143 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CELA1 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 43/293 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CFAP47 | c.8165G>T p.C2722F | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- CFAP74 | c.2698G>T p.D900Y | Missense Mutation (SNP) | VAF 178/540 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- CHD6 | c.3274del p.Y1092Tfs*9 | Frame Shift Del (DEL) | VAF 41/237 reads (17%) | called by mutect2, pindel, varscan2
- CHD9 | c.7459G>T p.V2487F (on ENST00000398510 / NM_001382353.1; = p.V2471F on NM_025134.7) | Missense Mutation (SNP) | VAF 31/195 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLCNKB | c.713G>T p.R238M | Missense Mutation (SNP) | VAF 141/388 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CMAS | c.1168C>G p.P390A | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNTN5 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- CNTNAP5 | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL5A2 | c.4288G>A p.D1430N | Missense Mutation (SNP) | VAF 31/264 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CORIN | c.2747C>A p.P916Q | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.169); called by muse, mutect2
- CPOX | c.80G>T p.W27L | Missense Mutation (SNP) | VAF 79/292 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CPS1 | c.1787G>T p.G596V | Missense Mutation (SNP) | VAF 31/352 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- CRAT | c.356G>T p.S119I | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRB1 | c.2447T>C p.F816S | Missense Mutation (SNP) | VAF 22/255 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.076); called by muse, mutect2
- CSMD3 | c.7817G>C p.S2606T (on ENST00000297405 / NM_001363185.1; = p.S2502T on NM_052900.3) | Missense Mutation (SNP) | VAF 18/158 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CSMD3 | c.5405G>A p.G1802D (on ENST00000297405 / NM_001363185.1; = p.G1698D on NM_052900.3) | Missense Mutation (SNP) | VAF 19/302 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- CSRP3 | c.245C>A p.T82K | Missense Mutation (SNP) | VAF 31/366 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.04); called by muse, mutect2
- CUBN | c.5525G>T p.G1842V | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CYHR1 | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- CYP46A1 | c.638A>T p.Q213L | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.007); called by muse, mutect2
- DCC | c.2020C>A p.L674M | Missense Mutation (SNP) | VAF 59/288 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- DDC | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 31/434 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- DDX11 | c.-4-1G>T | Splice Site (SNP) | VAF 45/215 reads (21%) | called by muse, mutect2, varscan2
- DENND2A | c.2355G>T p.M785I | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- DIPK2A | c.547T>A p.Y183N | Missense Mutation (SNP) | VAF 37/900 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- DISP1 | c.2740T>G p.F914V | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DLG3 | c.1774-1G>T p.X592_splice | Splice Site (SNP) | VAF 22/297 reads (7%) | called by muse, mutect2
- DNAH5 | c.4665G>T p.W1555C | Missense Mutation (SNP) | VAF 54/182 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH6 | c.10418G>T p.R3473I | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH9 | c.1847A>T p.E616V | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- DNAH9 | c.1848G>T p.E616D | Missense Mutation (SNP) | VAF 55/238 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- DOCK2 | c.5294C>A p.A1765E | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DSG3 | c.1811C>A p.P604H | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.383); called by muse, mutect2
- DSG4 | c.1075T>C p.Y359H | Missense Mutation (SNP) | VAF 33/153 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EGFL6 | c.410C>T p.T137I | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- EPB41L1 | c.489G>T p.R163= | Splice Region (SNP) | VAF 37/273 reads (14%) | called by muse, mutect2, varscan2
- EPHA6 | c.2816C>A p.P939Q | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ERICH1 | c.431A>T p.Q144L | Missense Mutation (SNP) | VAF 50/264 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- ESCO1 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 17/112 reads (15%) | called by muse, mutect2, varscan2
- ESCO1 | c.567T>A p.D189E | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT tolerated (0.41); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EZHIP | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 70/467 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- FAM171B | c.2192A>T p.H731L | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- FAM184B | c.1939G>T p.E647* | Nonsense Mutation (SNP) | VAF 40/518 reads (8%) | called by muse, mutect2
- FAM185A | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2
- FAM20B | c.79A>C p.N27H | Missense Mutation (SNP) | VAF 54/147 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- FAM50A | c.614A>G p.Y205C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- FAM81B | c.43dup p.R15Kfs*18 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel
- FBN2 | c.7370del p.P2457Qfs*34 | Frame Shift Del (DEL) | VAF 19/185 reads (10%) | called by mutect2, pindel, varscan2
- FBXO2 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.893); called by muse, mutect2
- FCGBP | c.10084C>T p.P3362S | Missense Mutation (SNP) | VAF 105/649 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FCRL5 | c.1783C>A p.P595T | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FER1L6 | c.4961A>T p.N1654I | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FHL1 | c.225G>C p.L75F | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- FLNB | c.2815G>C p.A939P | Missense Mutation (SNP) | VAF 66/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FMN2 | c.797G>T p.S266I | Missense Mutation (SNP) | VAF 108/229 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FMNL1 | c.1655C>A p.P552H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- FNDC1 | c.1627G>C p.E543Q | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.01); called by muse, mutect2
- FOXL1 | c.572C>A p.A191E | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.322); called by muse, mutect2, varscan2
- GABRA1 | c.1085T>C p.I362T | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GABRE | c.584G>T p.C195F | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GAL3ST4 | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 98/296 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- GAS2L2 | c.872C>A p.P291Q | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GEMIN7 | c.325A>T p.T109S | Missense Mutation (SNP) | VAF 27/231 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GET3 | c.576G>T p.Q192H | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- GFI1 | c.1009A>T p.T337S | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GJC2 | c.185G>C p.G62A | Missense Mutation (SNP) | VAF 31/559 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GK5 | c.1359C>G p.D453E | Missense Mutation (SNP) | VAF 59/255 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GOLGA6A | c.2046G>T p.Q682H | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2
- GPI | c.634-2A>T p.X212_splice | Splice Site (SNP) | VAF 55/442 reads (12%) | called by muse, mutect2, varscan2
- GRAMD4 | c.1235G>C p.R412P | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); called by muse, mutect2
- GRID2IP | c.53G>A p.G18D | Missense Mutation (SNP) | VAF 376/1052 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIP2 | c.1135G>T p.A379S (on ENST00000619221; = p.A282S on NM_001080423.4) | Missense Mutation (SNP) | VAF 61/219 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GSC | c.621G>A p.W207* | Nonsense Mutation (SNP) | VAF 28/326 reads (9%) | called by muse, mutect2
- H1-4 | c.178G>T p.A60S | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- HACE1 | c.557G>C p.S186T | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- HDX | c.1825-1G>T p.X609_splice | Splice Site (SNP) | VAF 12/63 reads (19%) | called by muse, mutect2, varscan2
- HEXIM1 | c.380C>T p.A127V | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); called by muse, mutect2
- HMCN2 | c.13540G>T p.V4514F | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.76); PolyPhen benign (0.003); called by muse, mutect2
- HNRNPL | c.1100del p.P367Hfs*28 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel
- HSD3B1 | c.661G>T p.V221F | Missense Mutation (SNP) | VAF 28/402 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); called by muse, mutect2
- HSDL1 | c.503A>T p.D168V | Missense Mutation (SNP) | VAF 37/388 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.653); called by muse, mutect2
- HYDIN | c.8305A>T p.T2769S | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by mutect2, varscan2
- IAPP | c.158G>T p.S53I | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- IGLV2-11 | c.310G>T p.E104* | Nonsense Mutation (SNP) | VAF 48/525 reads (9%) | called by muse, mutect2
- IGSF5 | c.783G>C p.L261F | Missense Mutation (SNP) | VAF 17/366 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.922); called by muse, mutect2
- INSL5 | c.74C>G p.S25C | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.533); called by muse, mutect2
- KALRN | c.7209G>T p.W2403C (on ENST00000360013 / NM_001024660.4; = p.W706C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/201 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNG4 | c.1273G>C p.V425L | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNH5 | c.2415T>G p.N805K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNT1 | c.2213C>A p.S738* (on ENST00000488444; = p.S757* on NM_020822.3) | Nonsense Mutation (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- KLHL20 | c.764A>T p.Q255L | Missense Mutation (SNP) | VAF 89/261 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- KRT2 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 34/155 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- KRTAP21-2 | c.192C>A p.S64R | Missense Mutation (SNP) | VAF 97/346 reads (28%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.5); called by muse, mutect2, varscan2
- KRTAP5-10 | c.560G>T p.C187F | Missense Mutation (SNP) | VAF 44/403 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LACC1 | c.928G>C p.G310R | Missense Mutation (SNP) | VAF 18/166 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- LACTBL1 | c.257C>A p.P86H (on ENST00000618559; = p.P115H on NM_001289974.2) | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- LAMB4 | c.548G>A p.C183Y | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- LAS1L | c.256C>A p.L86M | Missense Mutation (SNP) | VAF 26/177 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LCN9 | c.403A>T p.T135S | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.043); called by muse, mutect2
- LIPI | c.432T>A p.N144K | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- LIX1L | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 26/218 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- LMBRD1 | c.1502G>T p.R501L (on ENST00000649011; = p.R479L on NM_018368.4) | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2
- LMLN2 | c.1321G>C p.E441Q | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2
- LOXHD1 | c.3776G>T p.W1259L | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- LRIT1 | c.1516del p.R506Gfs*27 | Frame Shift Del (DEL) | VAF 123/528 reads (23%) | called by mutect2, pindel, varscan2
- LTBP4 | c.938G>T p.R313L (on ENST00000308370 / NM_001042544.1; = p.R276L on NM_003573.2) | Missense Mutation (SNP) | VAF 103/521 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- MACF1 | c.7771G>T p.D2591Y | Missense Mutation (SNP) | VAF 42/188 reads (22%) | called by muse, mutect2, varscan2
- MAGEB4 | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 41/216 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MAN1C1 | c.1127G>A p.G376E | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- MAP3K12 | c.1141A>T p.K381* | Nonsense Mutation (SNP) | VAF 39/159 reads (25%) | called by muse, mutect2, varscan2
- MCM8 | c.1423G>T p.V475L | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MECP2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 58/264 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MED13 | c.1166A>T p.Q389L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- MEGF10 | c.2161G>T p.G721* | Nonsense Mutation (SNP) | VAF 18/159 reads (11%) | called by muse, mutect2, varscan2
- MFN1 | c.517G>T p.D173Y | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MIIP | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.834); called by muse, mutect2
- MKRN3 | c.1238G>T p.G413V | Missense Mutation (SNP) | VAF 72/346 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MOGAT3 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 132/435 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.961C>A p.P321T | Missense Mutation (SNP) | VAF 159/567 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC2 | c.3788A>G p.Q1263R | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPS18A | c.287A>T p.H96L | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- MYB | c.330C>A p.Y110* | Nonsense Mutation (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- MYBPC3 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- MYO16 | c.5042C>T p.S1681L | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MYO9A | c.2155G>T p.G719W | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- NADK2 | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 15/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NCSTN | c.771G>C p.W257C | Missense Mutation (SNP) | VAF 66/414 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- NDST4 | c.1958del p.P653Lfs*64 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- NIBAN3 | c.1120C>A p.P374T | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, varscan2
- NIBAN3 | c.1233G>C p.Q411H | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.346); called by muse, varscan2
- NINL | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NLGN1 | c.2237C>A p.S746Y | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.35); called by muse, mutect2, varscan2
- NSD1 | c.5040G>C p.K1680N | Missense Mutation (SNP) | VAF 75/268 reads (28%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- NUTM2G | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- OBI1 | c.2037G>T p.M679I | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- OR10J5 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR10X1 | c.579C>A p.F193L | Missense Mutation (SNP) | VAF 16/292 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR13H1 | c.688C>A p.L230I | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- OR13J1 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- OR1C1 | c.897G>T p.R299S | Missense Mutation (SNP) | VAF 65/127 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR2M2 | c.820G>T p.V274L | Missense Mutation (SNP) | VAF 189/441 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.513); called by muse, mutect2, varscan2
- OR2T12 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 217/644 reads (34%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- OR4A15 | c.769G>T p.A257S | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.405); called by muse, mutect2, varscan2
- OR4C6 | c.600C>A p.N200K | Missense Mutation (SNP) | VAF 71/256 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4Q3 | c.424C>A p.L142I | Missense Mutation (SNP) | VAF 36/241 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- OR52E2 | c.827T>A p.L276H | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR5K3 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 68/362 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- OR5L2 | c.140C>A p.A47E | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- OR5M10 | c.43T>G p.L15V | Missense Mutation (SNP) | VAF 19/224 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.157); called by muse, mutect2
- OR8K5 | c.814A>C p.K272Q | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.951); called by muse, varscan2
- OR8K5 | c.86G>T p.G29V | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTOA | c.2308T>C p.F770L (on ENST00000286149; = p.F756L on NM_144672.4) | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT tolerated (0.88); PolyPhen benign (0.028); called by muse, mutect2
- OTOP2 | c.856C>G p.R286G | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- OTUD5 | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 103/649 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- P2RX5 | c.637G>T p.D213Y | Missense Mutation (SNP) | VAF 123/460 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- P2RY4 | c.736A>T p.T246S | Missense Mutation (SNP) | VAF 22/215 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PARP1 | c.1525G>T p.G509C | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.863); called by muse, mutect2
- PASD1 | c.721C>A p.Q241K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- PAX1 | c.1421A>T p.Q474L | Missense Mutation (SNP) | VAF 73/377 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCSK1N | c.106C>A p.P36T | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- PDE3A | c.2444G>T p.G815V | Missense Mutation (SNP) | VAF 11/212 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- PDX1 | c.105C>A p.C35* | Nonsense Mutation (SNP) | VAF 49/426 reads (12%) | called by muse, mutect2, varscan2
- PEX5L | c.1112C>A p.A371E | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLXDC2 | c.924G>T p.E308D | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.05); called by muse, mutect2
- PNMA5 | c.981T>G p.D327E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.134); called by muse, mutect2, varscan2
- POSTN | c.2343dup p.E782Rfs*11 | Frame Shift Ins (INS) | VAF 10/101 reads (10%) | called by mutect2, varscan2
- POU1F1 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 56/312 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- PPM1H | c.389G>T p.G130V | Missense Mutation (SNP) | VAF 23/228 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2
- PPP1R2B | c.97C>G p.R33G | Missense Mutation (SNP) | VAF 152/571 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRAMEF10 | c.1366C>G p.P456A | Missense Mutation (SNP) | VAF 30/282 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PRB1 | c.244C>A p.P82T | Missense Mutation (SNP) | VAF 47/162 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PRKCH | c.887G>T p.G296V | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKG1 | c.190A>G p.S64G | Missense Mutation (SNP) | VAF 36/466 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- PRR23B | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2
- PRR32 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 48/239 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PRSS21 | c.306G>T p.Q102H | Missense Mutation (SNP) | VAF 40/160 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- PRSS36 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 35/352 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- PRX | c.4367del p.A1456Vfs*29 | Frame Shift Del (DEL) | VAF 14/126 reads (11%) | called by mutect2, varscan2
- PSMC6 | c.796_799del p.E266Ffs*5 (on ENST00000612399; = p.E252Ffs*5 on NM_002806.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 18/116 reads (16%) | called by mutect2, pindel, varscan2
- RANBP2 | c.8560G>T p.A2854S | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RASD1 | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- RASSF4 | c.139-4A>G | Splice Region (SNP) | VAF 41/165 reads (25%) | called by muse, mutect2, varscan2
- RASSF6 | c.936+1G>T p.X312_splice (on ENST00000342081 / NM_201431.2; = p.X280_splice on NM_177532.5) | Splice Site (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- RBFOX1 | c.1191C>A p.Y397* | Nonsense Mutation (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2
- RFPL4B | c.695A>C p.H232P | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- RGPD3 | c.46C>A p.Q16K | Missense Mutation (SNP) | VAF 66/552 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- RGPD4 | c.2177G>T p.S726I | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- RLBP1 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 34/242 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RNF170 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNF175 | c.149C>A p.S50Y | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- RTEL1 | c.2393G>T p.S798I | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RTN1 | c.1974-2_1974-1del p.X658_splice | Splice Site (DEL) | VAF 16/116 reads (14%) | called by mutect2, pindel, varscan2
- RUFY4 | c.1300C>A p.Q434K | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- RUNDC3A | c.168G>T p.E56D | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.017); called by muse, mutect2
- SALL3 | c.2713C>A p.L905M | Missense Mutation (SNP) | VAF 50/247 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- SCN4A | c.1304C>T p.S435F | Missense Mutation (SNP) | VAF 88/317 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCNN1B | c.746G>T p.C249F | Missense Mutation (SNP) | VAF 32/395 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCNN1D | c.1846G>T p.G616W (on ENST00000338555; = p.G780W on NM_001130413.4) | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2
- SCYL1 | c.1915A>C p.S639R | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.019); called by muse, mutect2
- SDCCAG8 | c.1364G>T p.G455V | Missense Mutation (SNP) | VAF 128/323 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- SDK2 | c.364C>A p.Q122K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SEMA5B | c.1053G>T p.E351D | Missense Mutation (SNP) | VAF 92/417 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SEMA6D | c.2360C>T p.A787V (on ENST00000316364 / NM_153618.2; = p.A725V on NM_020858.2) | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- SERPINB3 | c.350A>T p.Q117L | Missense Mutation (SNP) | VAF 35/243 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SETD1A | c.4837C>G p.R1613G | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SFMBT2 | c.1616C>T p.S539L | Missense Mutation (SNP) | VAF 62/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SFTPA2 | c.481C>A p.R161S | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SGSH | c.13G>T p.V5L | Missense Mutation (SNP) | VAF 11/262 reads (4%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); called by muse, mutect2
- SIRPB1 | c.507C>A p.C169* | Nonsense Mutation (SNP) | VAF 70/454 reads (15%) | called by muse, mutect2, varscan2
- SLC12A9 | c.1184G>T p.W395L | Missense Mutation (SNP) | VAF 95/252 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SLC16A9 | c.1468A>G p.N490D | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT tolerated (0.57); PolyPhen benign (0.023); called by muse, mutect2
- SLC25A22 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 53/241 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- SLC2A11 | c.316G>T p.V106L (on ENST00000345044 / NM_001024938.4; = p.V113L on NM_030807.5) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC5A8 | c.297C>A p.S99R | Missense Mutation (SNP) | VAF 20/117 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); called by muse, mutect2
- SLC9A3 | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 114/295 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLFN5 | c.952A>G p.N318D | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SLITRK1 | c.1089C>A p.N363K | Missense Mutation (SNP) | VAF 24/263 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- SNCAIP | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 9/151 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.274); called by muse, mutect2
- SOX2 | c.760G>T p.V254L | Missense Mutation (SNP) | VAF 84/518 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SOX5 | c.1798C>A p.L600I | Missense Mutation (SNP) | VAF 118/387 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- SPPL2C | c.1737C>A p.D579E | Missense Mutation (SNP) | VAF 60/514 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPTLC3 | c.941G>A p.G314D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRSF8 | c.176T>G p.F59C | Missense Mutation (SNP) | VAF 36/242 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STKLD1 | c.1341G>C p.E447D | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.088); called by muse, mutect2
- SULF2 | c.1533C>A p.Y511* | Nonsense Mutation (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- TBC1D30 | c.1708G>T p.A570S (on ENST00000542120; = p.A407S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/233 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- TCF15 | c.152C>A p.P51Q | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TESMIN | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TEX13C | c.1373G>C p.S458T | Missense Mutation (SNP) | VAF 97/885 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- TEX15 | c.6943A>C p.T2315P (on ENST00000256246; = p.T2698P on NM_001350162.2) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- TG | c.1421G>T p.G474V | Missense Mutation (SNP) | VAF 34/394 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TICAM1 | c.1400A>G p.H467R | Missense Mutation (SNP) | VAF 105/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- TMEM131L | c.2809G>T p.D937Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM200A | c.748A>T p.S250C | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- TMEM215 | c.107C>A p.T36N | Missense Mutation (SNP) | VAF 28/345 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); called by muse, mutect2
- TNFRSF1B | c.359G>C p.C120S | Missense Mutation (SNP) | VAF 50/556 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TRBV2 | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- TRPM3 | c.4712C>A p.A1571D (on ENST00000357533 / NM_001366142.2; = p.A1426D on NM_020952.6) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM4 | c.2570G>A p.R857H | Missense Mutation (SNP) | VAF 101/354 reads (29%) | SIFT tolerated (0.4); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TUBB8 | c.268T>C p.F90L | Missense Mutation (SNP) | VAF 32/508 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.528); called by muse, mutect2
- TULP3 | c.287A>G p.D96G | Missense Mutation (SNP) | VAF 54/183 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UBA1 | c.739T>G p.F247V | Missense Mutation (SNP) | VAF 44/555 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2
- UGT2B28 | c.1202A>G p.D401G | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.093); called by muse, mutect2
- USH1G | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 111/445 reads (25%) | SIFT tolerated (0.81); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- USP26 | c.1868G>A p.R623K | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- VSIG10L | c.2261G>C p.G754A | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- VWA5A | c.32A>T p.H11L | Missense Mutation (SNP) | VAF 42/189 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- VWDE | c.1387G>A p.V463I | Missense Mutation (SNP) | VAF 20/601 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- XIRP2 | c.23G>T p.S8I (on ENST00000628543; = p.S183I on NM_152381.6) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.424); called by muse, varscan2
- XK | c.448C>G p.P150A | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZEB2 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- ZFYVE26 | c.3173G>C p.R1058P | Missense Mutation (SNP) | VAF 75/389 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZHX2 | c.1228G>T p.V410L | Missense Mutation (SNP) | VAF 22/280 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2
- ZNF334 | c.190C>A p.Q64K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.157); called by muse, varscan2
- ZNF418 | c.935G>T p.R312I | Missense Mutation (SNP) | VAF 19/207 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); called by muse, mutect2
- ZNF479 | c.1046G>T p.R349I | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2
- ZNF572 | c.956A>T p.Q319L | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF676 | c.1768G>T p.E590* (on ENST00000650058; = p.E558* on NM_001001411.3) | Nonsense Mutation (SNP) | VAF 11/256 reads (4%) | called by muse, mutect2
- ZNF700 | c.1031C>G p.S344C | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ZNF80 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 71/391 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF879 | c.1441G>T p.E481* | Nonsense Mutation (SNP) | VAF 43/169 reads (25%) | called by muse, mutect2, varscan2
- ABCB5 | c.1236G>A p.K412= | Silent (SNP) | VAF 16/182 reads (9%) | called by muse, mutect2
- ABCF2 | c.693G>T p.G231= | Silent (SNP) | VAF 36/107 reads (34%) | catalogued as rs1277639424; called by muse, mutect2, varscan2
- ABHD12B | c.606C>A p.T202= (on ENST00000337334 / NM_001206673.2; = p.T125= on NM_181533.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 54/227 reads (24%) | called by muse, mutect2, varscan2
- ACOT7 | c.873C>T p.T291= (on ENST00000377855 / NM_181864.3; = p.T281= on NM_007274.4) | Silent (SNP) | VAF 80/238 reads (34%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.1371T>A p.T457= | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- ADCY2 | c.2916C>T p.T972= | Silent (SNP) | VAF 16/286 reads (6%) | called by muse, mutect2
- ADGRL2 | c.3945G>T p.G1315= (on ENST00000370717 / NM_001366005.1; = p.G1259= on NM_012302.4) | Silent (SNP) | VAF 8/158 reads (5%) | catalogued as COSV54683097; called by muse, mutect2
- AHNAK2 | c.7800G>A p.A2600= | Silent (SNP) | VAF 31/380 reads (8%) | catalogued as rs749695866, COSV60907584; called by muse, mutect2
- AHNAK2 | c.6963C>A p.P2321= | Silent (SNP) | VAF 53/586 reads (9%) | called by muse, mutect2
- ANKRD18B | c.1506A>T p.T502= | Silent (SNP) | VAF 18/101 reads (18%) | called by muse, mutect2, varscan2
- ARMH4 | c.1200C>A p.P400= | Silent (SNP) | VAF 30/320 reads (9%) | called by muse, mutect2
- ATP2B3 | c.1857C>A p.L619= | Silent (SNP) | VAF 39/141 reads (28%) | called by muse, mutect2, varscan2
- ATP5F1C | c.228G>T p.L76= | Silent (SNP) | VAF 74/171 reads (43%) | called by muse, mutect2, varscan2
- B3GNT3 | c.639C>A p.V213= | Silent (SNP) | VAF 15/185 reads (8%) | called by muse, mutect2
- BANF1 | c.189G>A p.L63= | Silent (SNP) | VAF 97/732 reads (13%) | called by muse, mutect2, varscan2
- BNC2 | c.1833A>T p.P611= | Silent (SNP) | VAF 37/150 reads (25%) | called by muse, mutect2, varscan2
- BRSK1 | c.2035C>A p.R679= | Silent (SNP) | VAF 48/422 reads (11%) | catalogued as COSV100474820; called by mutect2, varscan2
- BRSK2 | c.1161C>T p.S387= | Silent (SNP) | VAF 40/319 reads (13%) | catalogued as rs564530908, COSV100373077, COSV57545765; called by muse, mutect2, varscan2
- BTBD11 | c.2340C>G p.P780= (on ENST00000280758 / NM_001018072.2; = p.P317= on NM_001017523.2) | Silent (SNP) | VAF 24/370 reads (6%) | catalogued as rs1234414492; called by muse, mutect2
- C16orf72 | c.51C>A p.P17= | Silent (SNP) | VAF 76/473 reads (16%) | called by muse, mutect2, varscan2
- CACNA1A | c.3429C>A p.T1143= | Silent (SNP) | VAF 4/17 reads (24%) | called by muse, mutect2, varscan2
- CACNA1H | c.4143G>A p.V1381= | Silent (SNP) | VAF 52/281 reads (19%) | called by mutect2, varscan2
- CALB1 | c.225T>A p.I75= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV99617845; called by muse, mutect2, varscan2
- CCDC120 | c.1557C>T p.P519= | Silent (SNP) | VAF 11/63 reads (17%) | catalogued as rs781935910; called by muse, mutect2, varscan2
- CCDC24 | c.756C>T p.C252= | Silent (SNP) | VAF 35/367 reads (10%) | catalogued as rs772687091, COSV62210939; called by muse, mutect2
- CEP295 | c.4971A>G p.P1657= | Silent (SNP) | VAF 55/220 reads (25%) | called by muse, mutect2, varscan2
- CHD4 | c.3648T>C p.D1216= (on ENST00000357008 / NM_001363606.2; = p.D1229= on NM_001273.5) | Silent (SNP) | VAF 70/223 reads (31%) | called by muse, mutect2, varscan2
- CHST13 | c.645C>T p.D215= | Silent (SNP) | VAF 19/243 reads (8%) | catalogued as rs764873281; called by muse, mutect2
- COL13A1 | c.753C>A p.P251= (on ENST00000398978 / NM_001130103.2; = p.P194= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs1158205767; called by muse, mutect2, varscan2
- COL4A3 | c.3483A>C p.G1161= | Silent (SNP) | VAF 46/388 reads (12%) | called by muse, mutect2, varscan2
- CR1 | c.5193T>A p.L1731= | Silent (SNP) | VAF 64/192 reads (33%) | called by muse, mutect2, varscan2
- CRYBG3 | c.3843A>T p.P1281= | Silent (SNP) | VAF 17/67 reads (25%) | called by muse, mutect2, varscan2
- CTNND2 | c.1866G>T p.G622= | Silent (SNP) | VAF 174/488 reads (36%) | catalogued as COSV100480792; called by muse, mutect2, varscan2
- CYP26A1 | c.294G>T p.R98= | Silent (SNP) | VAF 128/443 reads (29%) | called by muse, mutect2, varscan2
- D2HGDH | c.993G>T p.V331= | Silent (SNP) | VAF 36/386 reads (9%) | called by muse, mutect2
- DHX37 | c.3138G>A p.P1046= | Silent (SNP) | VAF 22/189 reads (12%) | catalogued as rs138599211; called by muse, mutect2, varscan2
- DMRT2 | c.1167A>T p.A389= | Silent (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2
- DNMT3B | c.1542C>T p.A514= | Silent (SNP) | VAF 48/308 reads (16%) | catalogued as rs140714949; called by muse, mutect2, varscan2
- DSG3 | c.30G>T p.G10= | Silent (SNP) | VAF 11/108 reads (10%) | called by muse, mutect2, varscan2
- ELFN1 | c.1443C>A p.A481= | Silent (SNP) | VAF 152/352 reads (43%) | called by muse, mutect2, varscan2
- FADS2 | c.294G>A p.E98= | Silent (SNP) | VAF 38/325 reads (12%) | called by muse, mutect2, varscan2
- FAM43A | c.843G>A p.E281= | Silent (SNP) | VAF 34/160 reads (21%) | catalogued as rs1228283073; called by muse, mutect2, varscan2
- FASN | c.1635C>A p.T545= | Silent (SNP) | VAF 98/507 reads (19%) | called by muse, mutect2, varscan2
- FAT4 | c.14331G>A p.G4777= | Silent (SNP) | VAF 21/158 reads (13%) | catalogued as rs1425448728, COSV100627129; called by muse, mutect2, varscan2
- FBLN1 | c.819C>T p.C273= | Silent (SNP) | VAF 24/360 reads (7%) | called by muse, mutect2
- FBLN2 | c.1041G>T p.T347= | Silent (SNP) | VAF 126/473 reads (27%) | called by muse, mutect2, varscan2
- FBXL7 | c.441G>T p.L147= | Silent (SNP) | VAF 199/555 reads (36%) | called by muse, mutect2, varscan2
- FOXB1 | c.435G>A p.T145= | Silent (SNP) | VAF 42/357 reads (12%) | catalogued as COSV101249727; called by muse, mutect2, varscan2
- FSIP2 | c.13329C>A p.I4443= | Silent (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- GAD2 | c.195G>T p.R65= | Silent (SNP) | VAF 20/322 reads (6%) | catalogued as COSV99392469; called by muse, mutect2
- GJD3 | c.771C>G p.P257= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- GLI2 | c.1755C>T p.D585= (on ENST00000361492 / NM_001374353.1; = p.D602= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 44/548 reads (8%) | catalogued as rs139202322; ClinVar: likely benign; called by muse, mutect2
- GOLGA1 | c.1020A>T p.A340= | Silent (SNP) | VAF 42/307 reads (14%) | called by muse, mutect2, varscan2
- GPC6 | c.1524G>T p.T508= | Silent (SNP) | VAF 55/618 reads (9%) | catalogued as COSV65502366, COSV65520565; called by muse, mutect2
- GUCY2C | c.286C>A p.R96= | Silent (SNP) | VAF 78/245 reads (32%) | called by muse, mutect2, varscan2
- IL6 | c.453C>A p.I151= | Silent (SNP) | VAF 18/322 reads (6%) | catalogued as COSV51733052, COSV51733961; called by muse, mutect2
- ITGA4 | c.765C>G p.V255= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV52000596; called by muse, mutect2, varscan2
- IWS1 | c.438A>T p.S146= | Silent (SNP) | VAF 21/234 reads (9%) | called by muse, mutect2
- KAT2A | c.1110A>C p.A370= | Silent (SNP) | VAF 48/261 reads (18%) | called by muse, mutect2, varscan2
- KCNJ5 | c.312C>T p.F104= | Silent (SNP) | VAF 32/539 reads (6%) | catalogued as rs201217363; ClinVar: benign; called by muse, mutect2
- KERA | c.390T>C p.D130= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as rs778810347; called by muse, mutect2, varscan2
- KIAA1109 | c.13053G>T p.G4351= | Silent (SNP) | VAF 16/188 reads (9%) | called by muse, mutect2
- KPRP | c.1008G>A p.R336= | Silent (SNP) | VAF 15/152 reads (10%) | called by muse, mutect2
- LAMA2 | c.3552G>T p.T1184= | Silent (SNP) | VAF 21/330 reads (6%) | catalogued as COSV70352761; called by muse, mutect2
- LNX1 | c.603C>T p.G201= (on ENST00000263925 / NM_001126328.3; = p.G105= on NM_032622.2) | Silent (SNP) | VAF 46/175 reads (26%) | called by muse, mutect2, varscan2
- MAGEC2 | c.375C>T p.G125= | Silent (SNP) | VAF 30/138 reads (22%) | catalogued as COSV55997761; called by muse, mutect2, varscan2
- MAPRE2 | c.360T>C p.L120= | Silent (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2, varscan2
- MAST2 | c.132G>T p.R44= | Silent (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- MGAT4C | c.819C>A p.A273= | Silent (SNP) | VAF 22/114 reads (19%) | called by muse, mutect2, varscan2
- MIDN | c.795C>T p.P265= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs376960542; called by muse, mutect2, varscan2
- MUC3A | c.9207C>T p.F3069= | Silent (SNP) | VAF 20/661 reads (3%) | catalogued as rs970230155; called by muse, mutect2
- MYO7B | c.3312C>G p.P1104= | Silent (SNP) | VAF 28/151 reads (19%) | called by muse, mutect2, varscan2
- MYO9A | c.2154T>C p.A718= | Silent (SNP) | VAF 44/196 reads (22%) | called by mutect2, varscan2
- NAALADL1 | c.465T>A p.P155= | Silent (SNP) | VAF 16/185 reads (9%) | called by muse, mutect2
- NEXMIF | c.3876C>A p.G1292= | Silent (SNP) | VAF 8/108 reads (7%) | catalogued as rs1443891211; called by muse, mutect2
- NFE2L3 | c.483G>T p.R161= | Silent (SNP) | VAF 143/423 reads (34%) | called by muse, mutect2, varscan2
- NPFFR1 | c.681G>A p.A227= | Silent (SNP) | VAF 63/353 reads (18%) | called by muse, mutect2, varscan2
- OGDH | c.1635G>T p.V545= | Silent (SNP) | VAF 96/257 reads (37%) | called by muse, mutect2, varscan2
- OPA3 | c.363G>C p.A121= | Silent (SNP) | VAF 74/417 reads (18%) | called by muse, mutect2, varscan2
- OPN5 | c.553C>T p.L185= | Silent (SNP) | VAF 10/186 reads (5%) | called by muse, mutect2
- OR4A15 | c.189T>C p.S63= | Silent (SNP) | VAF 36/260 reads (14%) | catalogued as COSV59035004; called by muse, mutect2, varscan2
- OTOP3 | c.933C>T p.T311= | Silent (SNP) | VAF 19/333 reads (6%) | catalogued as rs147650534; called by muse, mutect2
- OTULIN | c.984A>T p.P328= | Silent (SNP) | VAF 79/271 reads (29%) | called by muse, mutect2, varscan2
- PALD1 | c.1212G>A p.P404= | Silent (SNP) | VAF 18/226 reads (8%) | catalogued as rs570636561; called by muse, mutect2
- PARVB | c.921G>C p.L307= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- PCDH15 | c.4548A>T p.L1516= | Silent (SNP) | VAF 14/163 reads (9%) | called by muse, mutect2
- PCDHA6 | c.1839C>A p.P613= | Silent (SNP) | VAF 139/508 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA11 | c.1776G>A p.V592= | Silent (SNP) | VAF 79/355 reads (22%) | catalogued as rs779233337; called by muse, mutect2, varscan2
- PCDHGB5 | c.1881C>A p.A627= | Silent (SNP) | VAF 114/482 reads (24%) | catalogued as rs1395195387; called by muse, mutect2, varscan2
- PIEZO2 | c.318C>A p.I106= | Silent (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- PLXNB3 | c.3237G>A p.A1079= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as rs374159277; called by muse, mutect2, varscan2
- POTEF | c.2157C>A p.A719= | Silent (SNP) | VAF 51/708 reads (7%) | called by muse, mutect2
- PPFIA2 | c.3627C>T p.I1209= | Silent (SNP) | VAF 22/144 reads (15%) | called by muse, mutect2, varscan2
- PRLHR | c.333C>T p.T111= | Silent (SNP) | VAF 21/303 reads (7%) | catalogued as COSV53305000; called by muse, mutect2
- PRPF8 | c.3141G>A p.V1047= | Silent (SNP) | VAF 58/295 reads (20%) | catalogued as rs966875129; ClinVar: likely benign; called by muse, mutect2, varscan2
- PRR11 | c.981A>C p.P327= | Silent (SNP) | VAF 24/242 reads (10%) | catalogued as COSV51874742; called by muse, mutect2
- PTCD1 | c.1473G>C p.T491= | Silent (SNP) | VAF 95/705 reads (13%) | called by muse, mutect2, varscan2
- PTCHD3 | c.735G>A p.K245= | Silent (SNP) | VAF 20/248 reads (8%) | called by muse, mutect2
- RELN | c.9579C>T p.I3193= | Silent (SNP) | VAF 156/527 reads (30%) | called by muse, mutect2, varscan2
- RGS7 | c.1014G>A p.L338= | Silent (SNP) | VAF 54/257 reads (21%) | catalogued as rs142871760, COSV58564799; called by muse, mutect2, varscan2
- RICTOR | c.1959C>T p.T653= | Silent (SNP) | VAF 9/226 reads (4%) | called by muse, mutect2
- RP1L1 | c.5361G>A p.L1787= | Silent (SNP) | VAF 53/213 reads (25%) | catalogued as COSV66752207, COSV66759379; called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.21C>T p.D7= | Silent (SNP) | VAF 29/244 reads (12%) | catalogued as rs200710514; called by muse, mutect2, varscan2
- RRBP1 | c.540G>A p.V180= | Silent (SNP) | VAF 32/200 reads (16%) | called by muse, mutect2, varscan2
- RTL1 | c.1500C>T p.F500= | Silent (SNP) | VAF 12/73 reads (16%) | called by muse, mutect2, varscan2
- SAGE1 | c.15A>C p.P5= | Silent (SNP) | VAF 30/166 reads (18%) | called by muse, mutect2, varscan2
- SCN7A | c.4416G>A p.G1472= | Silent (SNP) | VAF 31/176 reads (18%) | called by muse, mutect2, varscan2
- SDK1 | c.5028A>T p.I1676= | Silent (SNP) | VAF 69/322 reads (21%) | called by muse, mutect2, varscan2
- SERPINA11 | c.324A>G p.T108= | Silent (SNP) | VAF 44/316 reads (14%) | catalogued as rs777116178; called by muse, mutect2, varscan2
- SLC17A8 | c.1314C>T p.H438= | Silent (SNP) | VAF 40/488 reads (8%) | called by muse, mutect2
- SLC35G3 | c.417C>A p.T139= | Silent (SNP) | VAF 233/994 reads (23%) | catalogued as rs1199144199; called by muse, mutect2, varscan2
- SLCO1B3 | c.75T>C p.N25= | Silent (SNP) | VAF 10/121 reads (8%) | called by muse, mutect2
- SPACA1 | c.331C>A p.R111= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as rs751066460, COSV52759409; called by muse, mutect2
- SPATA9 | c.279G>T p.L93= | Silent (SNP) | VAF 25/231 reads (11%) | called by muse, mutect2, varscan2
- SPRED2 | c.939G>A p.R313= | Silent (SNP) | VAF 20/296 reads (7%) | called by muse, mutect2
- SSTR5 | c.351G>A p.T117= | Silent (SNP) | VAF 28/296 reads (9%) | catalogued as rs761720839; called by muse, mutect2
- STAB2 | c.3366C>A p.I1122= | Silent (SNP) | VAF 7/157 reads (4%) | catalogued as COSV101185550; called by muse, mutect2
- STIL | c.1212A>C p.P404= | Silent (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- TBC1D12 | c.555G>T p.A185= | Silent (SNP) | VAF 21/401 reads (5%) | catalogued as COSV56553969; called by muse, mutect2
- TBC1D3F | c.811C>A p.R271= | Silent (SNP) | VAF 50/381 reads (13%) | called by muse, mutect2, varscan2
- TCHH | c.492C>T p.R164= | Silent (SNP) | VAF 13/220 reads (6%) | called by muse, mutect2
- TENM4 | c.3633C>T p.R1211= | Silent (SNP) | VAF 59/474 reads (12%) | called by muse, mutect2, varscan2
- TESK1 | c.42G>C p.G14= | Silent (SNP) | VAF 15/77 reads (19%) | called by muse, mutect2, varscan2
- TFAP2B | c.546T>A p.V182= | Silent (SNP) | VAF 47/171 reads (27%) | called by muse, mutect2, varscan2
- TMEM121B | c.831C>A p.P277= | Silent (SNP) | VAF 11/87 reads (13%) | catalogued as rs747710819; called by muse, mutect2
- TMEM229B | c.369C>G p.P123= | Silent (SNP) | VAF 40/560 reads (7%) | called by muse, mutect2
- TMEM35A | c.324C>A p.V108= | Silent (SNP) | VAF 47/186 reads (25%) | called by muse, mutect2, varscan2
- TRIM51GP | c.1125G>T p.V375= | Silent (SNP) | VAF 95/377 reads (25%) | called by muse, mutect2, varscan2
- TRIOBP | c.768G>C p.T256= | Silent (SNP) | VAF 67/379 reads (18%) | called by muse, mutect2, varscan2
- TTN | c.6954T>A p.R2318= (on ENST00000591111; = p.R2272= on NM_003319.4) | Silent (SNP) | VAF 31/305 reads (10%) | called by muse, mutect2, varscan2
- UBAC1 | c.771C>T p.S257= | Silent (SNP) | VAF 20/299 reads (7%) | catalogued as rs549228819; called by muse, mutect2
- VPS37A | c.66C>T p.L22= | Silent (SNP) | VAF 39/443 reads (9%) | catalogued as rs1171240851; called by muse, mutect2
- XRN2 | c.960C>T p.A320= | Silent (SNP) | VAF 37/245 reads (15%) | called by muse, mutect2, varscan2
- ZC3H12D | c.129G>C p.T43= | Silent (SNP) | VAF 34/172 reads (20%) | called by muse, mutect2, varscan2
- ZNF410 | c.1302G>A p.L434= | Silent (SNP) | VAF 32/144 reads (22%) | called by muse, mutect2, varscan2
- ZNF536 | c.681G>A p.P227= | Silent (SNP) | VAF 22/296 reads (7%) | catalogued as rs766672931; called by muse, mutect2
- ADAMTS17 | c.616+24318A>T | Intron (SNP) | VAF 38/141 reads (27%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-1262A>T | Intron (SNP) | VAF 78/272 reads (29%) | called by muse, mutect2, varscan2
- AKAP17A | c.1153-504G>A | Intron (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- AKT2 | c.*298G>T | 3'UTR (SNP) | VAF 18/116 reads (16%) | catalogued as COSV100251762; called by muse, mutect2, varscan2
- ANK2 | c.11611-546G>T | Intron (SNP) | VAF 22/182 reads (12%) | called by muse, mutect2, varscan2
- AP003548.1 | n.336-387G>T | Intron (SNP) | VAF 26/280 reads (9%) | called by muse, mutect2
- AVPR2 | chrX:153902558 C>T | 5'Flank (SNP) | VAF 7/46 reads (15%) | catalogued as rs781999099; called by muse, mutect2
- B3GALT5-AS1 | n.618G>T | RNA (SNP) | VAF 95/317 reads (30%) | called by muse, mutect2, varscan2
- BAIAP2 | chr17:81031289 C>G | 5'Flank (SNP) | VAF 17/213 reads (8%) | called by muse, mutect2
- CCDC198 | c.656-3977G>T | Intron (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- CENPE | c.-10G>A | 5'UTR (SNP) | VAF 24/245 reads (10%) | called by muse, mutect2
- CHAD | c.*474A>T | 3'UTR (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- CICP28 | chr7:56812015 G>T | 3'Flank (SNP) | VAF 32/340 reads (9%) | called by muse, mutect2
- COL6A5 | c.*128G>T | 3'UTR (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- CSNK2A1 | c.*5216G>T | 3'UTR (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2
- CYP4F8 | c.526-29G>T | Intron (SNP) | VAF 23/120 reads (19%) | called by muse, mutect2
- CYYR1 | c.-201C>T | 5'UTR (SNP) | VAF 60/259 reads (23%) | catalogued as rs1415184386; called by muse, mutect2, varscan2
- DERL3 | c.*2040T>A | 3'UTR (SNP) | VAF 19/142 reads (13%) | called by muse, mutect2, varscan2
- DKC1 | c.641-17G>T | Intron (SNP) | VAF 46/368 reads (13%) | called by muse, mutect2, varscan2
- DUSP22 | c.508+53G>C | Intron (SNP) | VAF 16/374 reads (4%) | catalogued as COSV100739812; called by muse, mutect2
- ECM2 | chr9:92536077 A>T | 5'Flank (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- FAM27E5 | n.250A>G | RNA (SNP) | VAF 28/119 reads (24%) | catalogued as rs1181510203; called by muse, mutect2, varscan2
- FAM3A | c.152-74G>T | Intron (SNP) | VAF 42/376 reads (11%) | called by muse, mutect2, varscan2
- FAM3A | c.152-75G>C | Intron (SNP) | VAF 41/373 reads (11%) | called by muse, mutect2, varscan2
- FANCM | c.5341-684G>T | Intron (SNP) | VAF 6/96 reads (6%) | called by muse, mutect2
- FBRSL1 | c.645+3358G>T | Intron (SNP) | VAF 38/241 reads (16%) | catalogued as rs908644180; called by muse, mutect2, varscan2
- FGF14 | c.608-39C>T | Intron (SNP) | VAF 21/246 reads (9%) | called by muse, mutect2
- FHL1 | c.*327G>C | 3'UTR (SNP) | VAF 20/159 reads (13%) | catalogued as rs1163673301; called by muse, mutect2, varscan2
- FREM2 | c.*45A>T | 3'UTR (SNP) | VAF 21/230 reads (9%) | catalogued as rs750612001; called by muse, mutect2
- FSD2 | c.*3374T>C | 3'UTR (SNP) | VAF 8/48 reads (17%) | called by muse, varscan2
- GLOD4 | chr17:782309 G>T | 5'Flank (SNP) | VAF 108/518 reads (21%) | catalogued as COSV56755631; called by muse, mutect2, varscan2
- GOSR2 | c.150-17C>G | Intron (SNP) | VAF 42/270 reads (16%) | catalogued as rs1202543887; called by muse, mutect2, varscan2
- GTF2IRD2P1 | n.2489C>A | RNA (SNP) | VAF 36/478 reads (8%) | called by muse, mutect2
- GUCY2D | c.2264-24del | Intron (DEL) | VAF 27/108 reads (25%) | called by mutect2, pindel, varscan2
- HDAC6 | c.999+32G>A | Intron (SNP) | VAF 27/220 reads (12%) | called by muse, mutect2, varscan2
- HLA-V | n.261G>T | RNA (SNP) | VAF 75/229 reads (33%) | called by muse, mutect2, varscan2
- HLA-V | n.262G>T | RNA (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- HSP90B3P | n.1015C>G | RNA (SNP) | VAF 18/340 reads (5%) | called by muse, mutect2
- IGHEP1 | n.588C>A | RNA (SNP) | VAF 33/424 reads (8%) | called by muse, mutect2
- IGKV2-29 | n.138G>T | RNA (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- KCNMA1 | c.2266+5740C>G | Intron (SNP) | VAF 31/177 reads (18%) | called by muse, mutect2, varscan2
- LASP1 | c.357+42G>T | Intron (SNP) | VAF 50/271 reads (18%) | called by muse, mutect2, varscan2
- LINC01561 | n.561C>A | RNA (SNP) | VAF 25/81 reads (31%) | called by muse, mutect2, varscan2
- LYSMD3 | c.256-945C>T | Intron (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2
- MAGEA5 | n.268C>A | RNA (SNP) | VAF 44/427 reads (10%) | called by muse, mutect2, varscan2
- MINDY3 | c.-15C>T | 5'UTR (SNP) | VAF 140/458 reads (31%) | called by muse, mutect2
- MS4A12 | c.276+16A>T | Intron (SNP) | VAF 9/66 reads (14%) | called by muse, mutect2, varscan2
- NDRG4 | c.22-69C>A | Intron (SNP) | VAF 14/281 reads (5%) | called by muse, mutect2
- NDUFAF5 | c.*369G>T | 3'UTR (SNP) | VAF 23/197 reads (12%) | called by muse, mutect2, varscan2
- NKAIN2 | c.474+20C>G | Intron (SNP) | VAF 13/170 reads (8%) | called by muse, mutect2
- NOC2LP2 | n.1768A>G | RNA (SNP) | VAF 21/216 reads (10%) | called by muse, mutect2
- PABPC1P2 | n.853G>A | RNA (SNP) | VAF 34/192 reads (18%) | catalogued as rs779714094; called by muse, mutect2, varscan2
- PIK3CD | c.-138+2132G>T | Intron (SNP) | VAF 41/618 reads (7%) | catalogued as COSV66098670; called by muse, mutect2
- PLD1 | c.2429+5101G>T | Intron (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- PPP2R2C | c.71-2313G>T | Intron (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- RAB5IF | c.*112C>T | 3'UTR (SNP) | VAF 32/350 reads (9%) | catalogued as rs138333574; called by muse, mutect2
- RABL6 | c.705+16G>C | Intron (SNP) | VAF 77/375 reads (21%) | called by muse, mutect2, varscan2
- RBM43 | c.3+321A>T | Intron (SNP) | VAF 82/590 reads (14%) | called by muse, mutect2, varscan2
- REC8 | c.737+25G>T | Intron (SNP) | VAF 23/244 reads (9%) | called by muse, mutect2
- RGPD1 | c.48+5797T>A | Intron (SNP) | VAF 25/418 reads (6%) | called by muse, mutect2
- RN7SL211P | chr2:64904509 C>T | 3'Flank (SNP) | VAF 103/341 reads (30%) | called by muse, mutect2, varscan2
- RN7SL262P | chrX:49157331 G>A | 3'Flank (SNP) | VAF 44/238 reads (18%) | catalogued as rs184732942; called by muse, mutect2, varscan2
- RPL10A | c.-2C>A | 5'UTR (SNP) | VAF 68/411 reads (17%) | catalogued as rs371703850; called by muse, mutect2, varscan2
- RPLP0P2 | n.1083G>T | RNA (SNP) | VAF 104/384 reads (27%) | called by muse, mutect2, varscan2
- SIGLEC17P | n.86G>T | RNA (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- SKOR1 | chr15:67823965 C>T | 5'Flank (SNP) | VAF 40/94 reads (43%) | called by muse, mutect2, varscan2
- SLC25A23 | c.*14C>T | 3'UTR (SNP) | VAF 19/225 reads (8%) | catalogued as rs748218826; called by muse, mutect2
- SLC35A2 | c.92-245G>T | Intron (SNP) | VAF 16/208 reads (8%) | called by muse, mutect2
- SLC4A3 | c.812-648G>A | Intron (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- SLC4A3 | c.812-647G>T | Intron (SNP) | VAF 18/95 reads (19%) | called by muse, mutect2, varscan2
- SMARCD2 | c.216+29G>T | Intron (SNP) | VAF 51/133 reads (38%) | called by muse, mutect2, varscan2
- SMIM27 | chr9:32552292 C>A | 5'Flank (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- SPEF2 | c.4448-3760T>C | Intron (SNP) | VAF 20/94 reads (21%) | catalogued as rs1318175577; called by muse, mutect2, varscan2
- SPHK2 | c.40-122C>G | Intron (SNP) | VAF 116/404 reads (29%) | called by muse, mutect2, varscan2
- SSPOP | n.14043C>T | RNA (SNP) | VAF 40/486 reads (8%) | catalogued as rs779784773; called by muse, mutect2
- SSPOP | n.14715G>T | RNA (SNP) | VAF 27/72 reads (38%) | catalogued as rs776273850, COSV100947114; called by muse, mutect2, varscan2
- STX3 | c.*5G>T | 3'UTR (SNP) | VAF 54/217 reads (25%) | called by muse, mutect2, varscan2
- TAC3 | c.*425C>A | 3'UTR (SNP) | VAF 25/132 reads (19%) | called by muse, mutect2, varscan2
- TBC1D31 | c.1032+1298C>T | Intron (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- TBX2 | chr17:61412588 C>A | 3'Flank (SNP) | VAF 45/174 reads (26%) | called by muse, mutect2, varscan2
- TGFBR3 | c.*366A>C | 3'UTR (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- TMEM135 | c.*6269G>T | 3'UTR (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- TMEM254 | c.88-117G>T | Intron (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- TPRX2P | n.657C>A | RNA (SNP) | VAF 17/95 reads (18%) | catalogued as rs778761121; called by muse, mutect2, varscan2
- TPRX2P | n.658C>G | RNA (SNP) | VAF 17/95 reads (18%) | called by muse, mutect2, varscan2
- TRO | c.45+23C>G | Intron (SNP) | VAF 8/70 reads (11%) | catalogued as rs780503781; called by muse, mutect2, varscan2
- TUBB7P | n.290C>T | RNA (SNP) | VAF 118/396 reads (30%) | catalogued as rs1307679818; called by muse, varscan2
- UBE3A | c.29+1482G>T | Intron (SNP) | VAF 33/120 reads (28%) | catalogued as COSV99218000; called by muse, mutect2, varscan2
- UBE3B | c.3015+250G>T | Intron (SNP) | VAF 13/87 reads (15%) | called by muse, mutect2, varscan2
- ZBTB44-DT | n.390G>A | RNA (SNP) | VAF 27/393 reads (7%) | catalogued as rs573666192; called by muse, mutect2
- ZFYVE26 | c.4675-16G>T | Intron (SNP) | VAF 80/301 reads (27%) | called by muse, mutect2, varscan2
- ZNF599 | c.18+82G>T | Intron (SNP) | VAF 16/200 reads (8%) | catalogued as rs1028254150; called by muse, mutect2
- ZNF99 | c.*347G>T | 3'UTR (SNP) | VAF 11/109 reads (10%) | catalogued as rs765153159, COSV68055780, COSV68056007; called by muse, mutect2, varscan2
